Somatic mutation profile of tumor specimen 0DGWOH from CCDI case PBBTZC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Cerebrum; Age at diagnosis: 5.9 years (2,166 days).
Specimen 0DGWOH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57f746ce-3946-497b-85e7-d8177119880e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGWOA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd5f06e1-0b3b-4f15-a490-875c1e845fef

The open-access MAF lists 20 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 8, Missense Mutation 7, Silent 3, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AL121899.2 | c.2077G>A p.D693N | Missense Mutation (SNP) | VAF 150/348 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as rs140423684, COSV101198425; called by muse, varscan2
- IL12RB1 | c.1550C>T p.T517M | Missense Mutation (SNP) | VAF 200/438 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.185); catalogued as rs372578469, COSV74045497; ClinVar: uncertain significance; called by muse, varscan2
- MAGEC3 | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 38/326 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.418); catalogued as COSV53579025; called by muse, varscan2
- PARG | c.2149C>T p.R717* | Nonsense Mutation (SNP) | VAF 117/364 reads (32%) | catalogued as rs544810287; called by muse, varscan2
- THSD7A | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 206/440 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV70259538; called by muse, varscan2
- CCDC102A | c.523G>C p.E175Q | Missense Mutation (SNP) | VAF 154/172 reads (90%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, varscan2
- TUB | c.841T>C p.Y281H (on ENST00000299506 / NM_177972.3; = p.Y336H on NM_003320.4) | Missense Mutation (SNP) | VAF 125/354 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- WWC2 | c.2906A>G p.D969G | Missense Mutation (SNP) | VAF 104/464 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.342); called by muse, varscan2
- AKAP8 | c.1206C>T p.D402= | Silent (SNP) | VAF 229/476 reads (48%) | catalogued as rs746292506; called by muse, varscan2
- C7 | c.660G>A p.R220= | Silent (SNP) | VAF 131/630 reads (21%) | catalogued as COSV57481206; called by muse, varscan2
- PTPRG | c.819C>T p.P273= | Silent (SNP) | VAF 154/366 reads (42%) | catalogued as rs371752893; called by muse, varscan2
- ANKRD28 | c.2784-41A>G | Intron (SNP) | VAF 8/80 reads (10%) | catalogued as rs1559312273; called by muse, varscan2
- ANKRD28 | c.2784-42C>T | Intron (SNP) | VAF 8/78 reads (10%) | called by muse, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 18/160 reads (11%) | called by muse, varscan2
- CALCOCO2 | c.825+77T>A | Intron (SNP) | VAF 20/154 reads (13%) | called by muse, varscan2
- CEP43 | c.301-89T>C | Intron (SNP) | VAF 8/70 reads (11%) | called by muse, varscan2
- CEP43 | c.301-88G>A | Intron (SNP) | VAF 8/70 reads (11%) | called by muse, varscan2
- CFAP65 | c.-2-93C>G | Intron (SNP) | VAF 3/22 reads (14%) | called by muse, varscan2
- GMEB2 | c.-19C>T | 5'UTR (SNP) | VAF 91/379 reads (24%) | catalogued as rs770246580, COSV99823915; called by muse, varscan2
- PAWR | c.684-53C>A | Intron (SNP) | VAF 41/85 reads (48%) | called by muse, varscan2
